Somatic mutation profile of tumor specimen C3N-02633-02 (aliquot CPT0182730006) from CPTAC case C3N-02633, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.7 years (20,362 days).
Specimen C3N-02633-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c03e20e0-3fa2-4b2e-b6f0-f827065bed75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02633-31 (Blood Derived Normal), aliquot CPT0182760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/810db28a-fe0e-43c1-8d37-1f50bd37fbc4

The open-access MAF lists 613 somatic variants for this specimen: 392 protein-altering or splice-affecting, 200 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 370, Silent 200, Intron 17, Nonsense Mutation 14, 5'Flank 3, Splice Site 3, Splice Region 2, In Frame Del 1, 3'UTR 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/347 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TUBB1 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 76/556 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs121918555, CM090175, COSV99414079; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1229G>A p.G410E (on ENST00000373993 / NM_138932.2; = p.G402E on NM_014576.4) | Missense Mutation (SNP) | VAF 151/304 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as COSV50983741, COSV50992038; called by muse, mutect2, varscan2
- ABCA13 | c.9406G>A p.E3136K | Missense Mutation (SNP) | VAF 194/754 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as COSV71289134; called by muse, mutect2
- ABO | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 171/465 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs782723901, COSV101505951, COSV71743423; called by muse, mutect2, varscan2
- AC011005.1 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 357/807 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs761380314; called by muse, mutect2
- ACAN | c.6883G>A p.E2295K | Missense Mutation (SNP) | VAF 126/383 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); catalogued as COSV61357872; called by muse, mutect2, varscan2
- ADAMTS19 | c.2350C>T p.H784Y | Missense Mutation (SNP) | VAF 110/430 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50781767; called by muse, mutect2, varscan2
- ADGRG4 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs866409405, COSV99795898; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by muse, mutect2, varscan2
- ANK3 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 186/357 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55046832; called by muse, mutect2, varscan2
- ANKRD55 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 105/378 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.284); catalogued as rs1027104164; called by muse, mutect2, varscan2
- ANO1 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756875910, COSV60280872; called by muse, mutect2, varscan2
- ANPEP | c.1699C>T p.L567F | Missense Mutation (SNP) | VAF 186/594 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364256395; called by muse, mutect2, varscan2
- APC | c.5959A>G p.I1987V | Missense Mutation (SNP) | VAF 112/344 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1269798265, CD961782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF1 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 116/305 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV51602977; called by muse, mutect2, varscan2
- ARMC4 | c.1239G>A p.R413= | Splice Region (SNP) | VAF 62/163 reads (38%) | catalogued as rs765937444, COSV53468351; called by muse, mutect2, varscan2
- ATG7 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 159/338 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61614022; called by muse, mutect2, varscan2
- ATP2A3 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 88/474 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59228661, COSV99989130; called by muse, mutect2, varscan2
- BANK1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV59839694; called by muse, mutect2, varscan2
- BFAR | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs752398303, COSV55492550; called by muse, mutect2, varscan2
- BLNK | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 146/303 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV56413764; called by muse, mutect2, varscan2
- BPTF | c.5575C>G p.R1859G | Missense Mutation (SNP) | VAF 156/401 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58838517; called by muse, mutect2, varscan2
- CACNA1E | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 217/576 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100705175; called by muse, varscan2
- CACNA1H | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 199/484 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1408374623, COSV100671011; called by muse, mutect2, varscan2
- CAMK4 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 166/565 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56660930; called by muse, mutect2, varscan2
- CASP8 | c.1090A>G p.N364D (on ENST00000432109 / NM_033355.3; = p.N381D on NM_001228.4) | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs765581502; called by muse, mutect2, varscan2
- CDK11A | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62264591, COSV62266754; called by muse, mutect2, varscan2
- CDKN2AIP | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs1025468818; called by muse, mutect2, varscan2
- CFAP47 | c.9023G>A p.R3008K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as rs1556019247; called by muse, mutect2, varscan2
- CFAP61 | c.2852A>T p.N951I | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs367847054; called by muse, mutect2, varscan2
- CFHR3 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs1156859095, COSV66401929; called by muse, mutect2, varscan2
- CFHR5 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV56830041; called by muse, mutect2, varscan2
- CHAMP1 | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 90/548 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV63521803; called by muse, mutect2, varscan2
- CNTN5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 125/347 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201638465, COSV54278829; called by muse, mutect2, varscan2
- COL3A1 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1443018018; called by muse, mutect2, varscan2
- COL5A3 | c.4556C>T p.S1519L | Missense Mutation (SNP) | VAF 210/639 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1027315262; called by muse, mutect2, varscan2
- CPS1 | c.1073A>T p.D358V | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826337; called by muse, mutect2, varscan2
- CSNKA2IP | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 158/370 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs935252709, COSV68072668; called by muse, mutect2, varscan2
- CYP19A1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 163/508 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs770120065, COSV53057383; called by muse, mutect2, varscan2
- DDR1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 133/805 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as rs145280414; called by muse, mutect2, varscan2
- DDX10 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 92/413 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs759430194; called by muse, mutect2, varscan2
- DNAH3 | c.5701C>T p.H1901Y | Missense Mutation (SNP) | VAF 170/444 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV54509498; called by muse, mutect2, varscan2
- DOK7 | c.1256G>A p.S419N | Missense Mutation (SNP) | VAF 112/514 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV60773743; called by muse, mutect2, varscan2
- DPP6 | c.958G>A p.D320N (on ENST00000377770 / NM_001364500.2; = p.D258N on NM_001936.5) | Missense Mutation (SNP) | VAF 86/566 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV59606371; called by muse, mutect2, varscan2
- DST | c.3971G>A p.S1324N (on ENST00000361203 / NM_001374722.1; = p.S998N on NM_001723.6) | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99758325; called by muse, mutect2, varscan2
- EDN3 | c.664G>A p.A222T (on ENST00000337938 / NM_001302455.2; = p.A208T on NM_207033.3) | Missense Mutation (SNP) | VAF 83/625 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs201352056; called by muse, mutect2, varscan2
- EPHA6 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 190/501 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67558967; called by muse, mutect2, varscan2
- EPS15 | c.2282C>T p.S761L | Missense Mutation (SNP) | VAF 148/395 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV65543118; called by muse, mutect2, varscan2
- EXOC1L | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 61/256 reads (24%) | catalogued as rs1426277040; called by muse, mutect2, varscan2
- EYA1 | c.1468C>T p.H490Y | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs748575456; called by muse, mutect2, varscan2
- FAM155A | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 106/705 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV65565998, COSV65579689; called by muse, mutect2
- FAM234B | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 176/674 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1274841247, COSV99546146; called by muse, mutect2, varscan2
- FAM90A1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 185/856 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.97); catalogued as COSV56715226; called by muse, mutect2, varscan2
- FBN3 | c.5570G>A p.G1857E | Missense Mutation (SNP) | VAF 123/355 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54457581; called by muse, mutect2, varscan2
- FGF9 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs868277032; called by muse, mutect2, varscan2
- FGG | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as CD1515064, COSV60196850; called by muse, mutect2, varscan2
- FHL5 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs868468680, COSV58739330; called by muse, mutect2, varscan2
- FHL5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV58735980; called by muse, mutect2, varscan2
- FSIP2 | c.13472G>A p.R4491K | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.146); catalogued as rs1212542781; called by muse, mutect2, varscan2
- GABRA4 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51922613; called by muse, mutect2, varscan2
- GLYATL1 | c.749G>A p.R250Q (on ENST00000317391 / NM_001354699.1; = p.R281Q on NM_080661.4) | Missense Mutation (SNP) | VAF 93/427 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs145479301; called by muse, mutect2, varscan2
- GNAS | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 167/495 reads (34%) | catalogued as rs1418473323, COSV58343114; called by muse, mutect2, varscan2
- GPC5 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs148600376, COSV65582933; called by muse, mutect2, varscan2
- GPRC6A | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV100114804; called by muse, mutect2, varscan2
- GRIN2A | c.2745G>T p.M915I | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100411396; called by muse, mutect2, varscan2
- GRXCR1 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1414314632, COSV101295690, COSV67674123; called by muse, mutect2, varscan2
- H3C11 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 66/415 reads (16%) | catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- HDDC3 | c.168+1G>A p.X56_splice | Splice Site (SNP) | VAF 147/394 reads (37%) | catalogued as rs746267075; called by muse, mutect2, varscan2
- HHLA1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70152893; called by muse, mutect2, varscan2
- HOXB13 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99284844; called by muse, mutect2, varscan2
- IGHV2-70 | c.95A>T p.K32I | Missense Mutation (SNP) | VAF 234/476 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371469802; called by muse, mutect2, varscan2
- IGSF9B | c.3929C>T p.T1310M | Missense Mutation (SNP) | VAF 116/571 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs760102783; called by muse, mutect2, varscan2
- KCNH5 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 89/555 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59770208; called by muse, mutect2, varscan2
- KCNS2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 98/448 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54641670; called by muse, mutect2, varscan2
- KIF18A | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150184870; called by muse, mutect2, varscan2
- KIF2C | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 127/254 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1187551672; called by muse, mutect2, varscan2
- LAT | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 79/506 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57953567; called by muse, mutect2, varscan2
- LDLR | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 168/549 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1035071612, COSV52941848; called by muse, mutect2, varscan2
- LMTK2 | c.4445C>T p.S1482F | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867251926, COSV99808049; called by muse, mutect2, varscan2
- LRCH4 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs1562805360, COSV59644581; called by muse, mutect2, varscan2
- LRFN2 | c.1259G>A p.S420N | Missense Mutation (SNP) | VAF 257/570 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs912342005; called by muse, mutect2, varscan2
- MAP3K9 | c.2492C>T p.S831F (on ENST00000554752 / NM_001284230.1; = p.S845F on NM_033141.4) | Missense Mutation (SNP) | VAF 308/639 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV67122689; called by muse, mutect2, varscan2
- MBD1 | c.1799C>T p.P600L (on ENST00000269468 / NM_001323950.1; = p.P498L on NM_002384.2) | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs369630777, COSV54004118; called by muse, mutect2, varscan2
- MCM3AP | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs771809009; called by muse, mutect2, varscan2
- MCM6 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1313858994, COSV51467700, COSV51470647; called by muse, mutect2, varscan2
- ME1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs1024613609, COSV63838552; called by muse, mutect2, varscan2
- MINDY4 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 138/489 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54678840; called by muse, mutect2, varscan2
- MN1 | c.3946G>T p.V1316L | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56557751; called by muse, mutect2, varscan2
- MROH2B | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 139/495 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101270905, COSV68188772; called by muse, mutect2, varscan2
- MROH2B | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1453679037, COSV68181483; called by muse, mutect2, varscan2
- MUC16 | c.39653G>A p.G13218D | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs1407435158; called by muse, mutect2, varscan2
- MUC16 | c.29495C>T p.A9832V | Missense Mutation (SNP) | VAF 145/497 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); catalogued as COSV67458979; called by muse, mutect2, varscan2
- MUC16 | c.24256C>T p.P8086S | Missense Mutation (SNP) | VAF 189/602 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as rs1207498258, COSV67443084; called by muse, mutect2, varscan2
- MUC16 | c.13940C>T p.P4647L | Missense Mutation (SNP) | VAF 178/570 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.649); catalogued as rs1171710802; called by muse, mutect2, varscan2
- MUC16 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 162/484 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV67446876; called by muse, mutect2, varscan2
- MUC4 | c.9568C>T p.P3190S | Missense Mutation (SNP) | VAF 155/685 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.65); catalogued as rs767249982; called by muse, mutect2, varscan2
- MUC5B | c.4367C>T p.T1456I | Missense Mutation (SNP) | VAF 202/519 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs771718595; called by muse, mutect2, varscan2
- MYH13 | c.5473G>A p.E1825K | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1164342553, COSV52831257; called by muse, mutect2, varscan2
- MYH2 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV104393378; called by muse, mutect2, varscan2
- MYO15B | c.6656C>T p.P2219L | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as rs1275177950; called by muse, mutect2, varscan2
- MYO18B | c.7387G>A p.G2463S | Missense Mutation (SNP) | VAF 189/407 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV59129369; called by muse, mutect2, varscan2
- NBAS | c.5882C>T p.S1961L | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs867036009, COSV55729016; called by muse, mutect2, varscan2
- NKX2-1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 112/666 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as CM087107; called by muse, mutect2, varscan2
- NKX2-2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 127/431 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs1212106777, COSV101010566; called by muse, mutect2, varscan2
- NRXN1 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.963); catalogued as rs1375865789; called by muse, mutect2, varscan2
- NSUN7 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs766932705; called by muse, mutect2, varscan2
- OBSCN | c.6817G>A p.V2273I | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.519); catalogued as COSV52777851; called by muse, mutect2
- OBSCN | c.14503-1G>A p.X4835_splice | Splice Site (SNP) | VAF 208/470 reads (44%) | catalogued as COSV52832383; called by muse, mutect2, varscan2
- OLFML2B | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs767261664, COSV54193984, COSV54200629; called by muse, mutect2, varscan2
- OR2C1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 194/461 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV59240770; called by muse, mutect2, varscan2
- OR2M7 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 173/663 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1477304501, COSV100522529; called by muse, mutect2, varscan2
- OR4A15 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 92/421 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.269); catalogued as rs774979270, COSV59035396; called by muse, mutect2, varscan2
- OR52B2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 184/451 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1290997076, COSV73209360; called by muse, mutect2, varscan2
- OR5D18 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 93/498 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV61738157; called by muse, mutect2, varscan2
- OR6N1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 271/671 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58647527; called by muse, mutect2, varscan2
- OR8K5 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 92/481 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57888517; called by muse, mutect2, varscan2
- OTOG | c.4856C>T p.S1619L | Missense Mutation (SNP) | VAF 151/492 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs867891665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PADI2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs375141021; called by muse, mutect2, varscan2
- PAK5 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 84/543 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308740724; called by muse, mutect2, varscan2
- PALD1 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 164/327 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs1047121221; called by muse, mutect2, varscan2
- PALM | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 170/516 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52768556; called by muse, mutect2, varscan2
- PCDHA13 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 180/606 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as rs781786717, COSV56509806; called by muse, varscan2
- PCDHA8 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 98/362 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs782217721, COSV65334558; called by muse, varscan2
- PCDHAC1 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 140/471 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53862707; called by muse, mutect2, varscan2
- PCDHB6 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 136/442 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV50690449, COSV50693465; called by muse, mutect2, varscan2
- PCLO | c.11815C>T p.Q3939* | Nonsense Mutation (SNP) | VAF 56/327 reads (17%) | catalogued as COSV100436264; called by muse, mutect2, varscan2
- PCNX2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 188/671 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99268376; called by muse, mutect2, varscan2
- PEAR1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 175/648 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs773000035; called by muse, mutect2, varscan2
- PENK | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 116/486 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573652413, COSV59240213, COSV59242061; called by muse, mutect2, varscan2
- PHKA1 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 84/242 reads (35%) | catalogued as COSV100262746; called by muse, mutect2, varscan2
- PHKG1 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 144/439 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs369323877; called by muse, mutect2
- PIK3R5 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV52659803; called by muse, mutect2, varscan2
- PLAGL2 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 146/495 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.943); catalogued as rs773671880; called by muse, mutect2, varscan2
- PLCH1 | c.4501G>A p.E1501K (on ENST00000340059 / NM_001130960.2; = p.E1493K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58187761; called by muse, mutect2, varscan2
- PLIN4 | c.1415G>A p.G472D (on ENST00000301286; = p.G487D on NM_001367868.2) | Missense Mutation (SNP) | VAF 241/765 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.365); catalogued as COSV56698578; called by muse, mutect2, varscan2
- PLK2 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 187/626 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs760418512; called by muse, mutect2, varscan2
- PRAMEF17 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 181/457 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs769736204; called by muse, mutect2, varscan2
- PRAMEF19 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs12123403; called by muse, mutect2, varscan2
- PRMT8 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 212/451 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs373595465; called by muse, mutect2, varscan2
- PTAFR | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 106/494 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV59536942; called by muse, mutect2, varscan2
- PTGER4 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 163/504 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100201793; called by muse, mutect2, varscan2
- PTPRT | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.348); catalogued as COSV61962458; called by muse, varscan2
- RBM26 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.306); catalogued as COSV57399221; called by muse, mutect2, varscan2
- RGPD3 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV100449972; called by muse, mutect2, varscan2
- RGPD4 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs755945836, COSV100736546; called by muse, mutect2, varscan2
- RIC3 | c.884C>T p.S295L (on ENST00000309737 / NM_001206671.4; = p.S294L on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs751315626; called by muse, mutect2, varscan2
- RNF130 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 71/453 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.5); catalogued as rs201925862; called by muse, mutect2, varscan2
- RNF148 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 303/615 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV57349680; called by muse, mutect2, varscan2
- RP1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV55111256; called by muse, mutect2, varscan2
- RTP5 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 121/504 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs546584865; called by muse, varscan2
- RUNDC1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 80/399 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs760086639, COSV64512497; called by muse, mutect2, varscan2
- RUNDC3B | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV56696166; called by muse, mutect2, varscan2
- RYR1 | c.11303G>A p.R3768Q | Missense Mutation (SNP) | VAF 151/420 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1214804010; called by muse, mutect2, varscan2
- S1PR4 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 238/726 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.656); catalogued as rs779851976; called by muse, mutect2, varscan2
- SALL1 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 97/557 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51759852; called by muse, mutect2, varscan2
- SAMSN1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.538); catalogued as COSV53467586; called by muse, mutect2, varscan2
- SCGN | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV58546808; called by muse, mutect2, varscan2
- SCN3A | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV51803632; called by muse, mutect2, varscan2
- SCN9A | c.5064G>A p.M1688I (on ENST00000303354; = p.M1677I on NM_002977.3) | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.625); catalogued as rs866205197; called by muse, mutect2, varscan2
- SERPINB11 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs751122140; called by muse, mutect2, varscan2
- SHISA9 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 104/539 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs973521357; called by muse, mutect2, varscan2
- SI | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140611221; called by muse, mutect2, varscan2
- SLC16A14 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 128/339 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs1404835517, COSV54617472, COSV99725656; called by muse, mutect2, varscan2
- SLC16A3 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 91/471 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs766184108; called by muse, mutect2, varscan2
- SLC52A1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs750821700, COSV54693142; called by muse, mutect2, varscan2
- SLC52A2 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 173/466 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV57350873; called by muse, mutect2, varscan2
- SLC7A13 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867672302, COSV52534202; called by muse, mutect2, varscan2
- SNX18 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 124/380 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV57988635; called by muse, mutect2, varscan2
- SOCS4 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs756340416, COSV59459910; called by muse, mutect2, varscan2
- SOX4 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774049259; called by muse, mutect2, varscan2
- SPTBN1 | c.7000G>A p.V2334I | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as rs150630405, COSV63339016; called by muse, mutect2, varscan2
- TACR3 | c.993G>A p.W331* | Nonsense Mutation (SNP) | VAF 76/389 reads (20%) | catalogued as rs1391626331, COSV59210192; called by muse, mutect2, varscan2
- TAS2R16 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 236/467 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50799311; called by muse, mutect2, varscan2
- TBC1D17 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746925907; called by muse, mutect2, varscan2
- TDRD12 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs1161289989; called by muse, mutect2, varscan2
- TERF1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 156/454 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.859); catalogued as rs748154619; called by muse, mutect2, varscan2
- TEX2 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 155/425 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs760701008; called by muse, mutect2, varscan2
- THEGL | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 81/316 reads (26%) | catalogued as rs748146057; called by muse, mutect2, varscan2
- THSD4 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 164/517 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55972594; called by muse, mutect2, varscan2
- THSD7B | c.4555G>A p.D1519N (on ENST00000272643; = p.D1517N on NM_001316349.2) | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as COSV55694688; called by muse, mutect2, varscan2
- TJP3 | c.1401G>A p.W467* | Nonsense Mutation (SNP) | VAF 62/216 reads (29%) | catalogued as COSV99516366; called by muse, mutect2, varscan2
- TMC5 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV101196714; called by muse, mutect2, varscan2
- TP63 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs148052765, COSV53211567; called by muse, mutect2, varscan2
- TRAT1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 147/445 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV55467551, COSV55467662; called by muse, mutect2, varscan2
- TRAV18 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 70/401 reads (17%) | catalogued as rs1256200830; called by muse, mutect2, varscan2
- TRHR | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 62/427 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV61233441; called by muse, mutect2, varscan2
- TRIM49B | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.107); catalogued as rs1210236467; called by muse, mutect2, varscan2
- TRIM56 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 211/534 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60157335; called by muse, mutect2, varscan2
- TRRAP | c.10046C>T p.S3349F (on ENST00000359863 / NM_001244580.1; = p.S3320F on NM_003496.3) | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV62850534; called by muse, mutect2, varscan2
- TSBP1 | c.991G>A p.G331R (on ENST00000617061; = p.Q334= on NM_006781.5) | Missense Mutation (SNP) | VAF 378/733 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as rs755699475; called by muse, mutect2, varscan2
- TTN | c.45466C>T p.R15156C (on ENST00000591111; = p.R7732C on NM_003319.4) | Missense Mutation (SNP) | VAF 55/246 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs1015961035, COSV60346478; called by muse, mutect2, varscan2
- TTN | c.24725G>A p.R8242K (on ENST00000591111; = p.R7315K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/249 reads (21%) | PolyPhen benign (0.001); catalogued as rs745818225, COSV59968547; called by muse, mutect2, varscan2
- TTN | c.19934G>A p.G6645E (on ENST00000591111; = p.G5718E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/310 reads (24%) | PolyPhen probably damaging (0.993); catalogued as rs531296995; called by muse, mutect2, varscan2
- USH2A | c.9049G>A p.D3017N | Missense Mutation (SNP) | VAF 125/366 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1222358142; called by muse, mutect2, varscan2
- USH2A | c.3449G>A p.G1150E | Missense Mutation (SNP) | VAF 244/608 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56375473; called by muse, mutect2, varscan2
- USH2A | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56327755; called by muse, mutect2, varscan2
- USP6 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 127/386 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV51473699; called by muse, mutect2, varscan2
- USPL1 | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 97/519 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs373409567; called by muse, mutect2, varscan2
- VWA5A | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs201353218, COSV63707984; called by muse, mutect2, varscan2
- XIRP1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 141/420 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs768874233; called by muse, mutect2, varscan2
- ZBED9 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 92/627 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV71729773; called by muse, mutect2, varscan2
- ZC3H18 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 170/458 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs1206315811; called by muse, mutect2, varscan2
- ZC3H18 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 68/377 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV56324921; called by muse, mutect2, varscan2
- ZDHHC11 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 29/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99362859; called by muse, mutect2
- ZFR2 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 195/620 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.433); catalogued as rs747794624; called by mutect2, varscan2
- ZNF469 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 87/522 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs865907429; called by muse, varscan2
- ZNF600 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 89/441 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as COSV57741924; called by muse, mutect2, varscan2
- ZNF638 | c.4633G>T p.D1545Y | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52486012; called by muse, mutect2, varscan2
- ZNF738 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1381117352; called by muse, mutect2, varscan2
- ACBD3 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 139/984 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ADAM22 | c.1193G>A p.W398* | Nonsense Mutation (SNP) | VAF 67/367 reads (18%) | called by muse, mutect2, varscan2
- ADGRF3 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- AIM2 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 191/491 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ALB | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ALCAM | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD24 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 165/549 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD55 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 104/373 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ANKRD61 | c.1037_1045del p.N346_G348del | In Frame Del (DEL) | VAF 102/489 reads (21%) | called by mutect2, pindel, varscan2
- ANO6 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOB | c.11377G>A p.E3793K | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP30 | c.3185C>T p.S1062F (on ENST00000368013 / NM_001025598.2; = p.S851F on NM_181720.3) | Missense Mutation (SNP) | VAF 278/709 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ARHGAP36 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGEF33 | c.494C>G p.A165G | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ARID1B | c.4483C>T p.H1495Y | Missense Mutation (SNP) | VAF 101/356 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ATG4D | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 77/494 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- AXL | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL9L | c.3538C>A p.P1180T | Missense Mutation (SNP) | VAF 98/469 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- BRSK1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 147/410 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BUB1B | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 101/340 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- BX276092.9 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- C17orf80 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 188/474 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2
- CAMSAP3 | c.2083G>A p.G695R | Missense Mutation (SNP) | VAF 188/589 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CAPN15 | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 246/583 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASR | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC82 | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDK5R2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 103/431 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CFAP47 | c.3017G>A p.G1006E | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHGB | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 123/356 reads (35%) | called by muse, mutect2, varscan2
- CIAPIN1 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CLDN12 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 73/394 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPOX | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 144/402 reads (36%) | called by muse, mutect2, varscan2
- CPS1 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CR1 | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 187/675 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CRYBG3 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CYB5D2 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- DDR2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 205/466 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DHX8 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 85/439 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DIS3L2 | c.1880A>G p.Q627R | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, varscan2
- DNAH9 | c.184_186dup p.R62dup | In Frame Ins (INS) | VAF 98/580 reads (17%) | called by mutect2, pindel, varscan2
- DNM1L | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 280/634 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DOCK3 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 138/353 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DOCK6 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 117/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.7702C>T p.H2568Y | Missense Mutation (SNP) | VAF 159/316 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHBP1L1 | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 208/560 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, varscan2
- ELP2 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EYS | c.5752G>A p.G1918R | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.4213C>T p.P1405S | Missense Mutation (SNP) | VAF 213/414 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- EZR | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- FAM155A | c.588T>A p.S196R | Missense Mutation (SNP) | VAF 109/708 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- FAM227A | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 107/224 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FAT3 | c.1855A>T p.N619Y | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLNB | c.4241C>T p.P1414L | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FLT3 | c.2347C>A p.L783I | Missense Mutation (SNP) | VAF 64/455 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGB1 | c.2791C>T p.L931F | Missense Mutation (SNP) | VAF 140/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GREB1 | c.5131C>T p.P1711S | Missense Mutation (SNP) | VAF 112/405 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GRIA2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- GRIA3 | c.1479G>A p.M493I | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- HOXA10 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 108/723 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- HTR4 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 133/457 reads (29%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR6 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 105/556 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HYDIN | c.12097A>T p.K4033* | Nonsense Mutation (SNP) | VAF 54/335 reads (16%) | called by muse, mutect2, varscan2
- HYDIN | c.9821C>T p.S3274F | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- IFT57 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL20RA | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 92/383 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IL22RA2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IMPACT | c.458C>G p.A153G | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- INVS | c.1244G>T p.R415M | Missense Mutation (SNP) | VAF 124/231 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IQUB | c.1187A>C p.N396T | Missense Mutation (SNP) | VAF 165/353 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IRX6 | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 198/532 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IZUMO3 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 187/379 reads (49%) | SIFT tolerated (0.87); called by muse, mutect2, varscan2
- KCNH7 | c.2560C>T p.H854Y | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNT2 | c.3035G>A p.R1012K | Missense Mutation (SNP) | VAF 208/525 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by mutect2, varscan2
- KIF26A | c.3472T>G p.S1158A | Missense Mutation (SNP) | VAF 341/684 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KITLG | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCE1C | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 196/722 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LILRA1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 160/478 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MALRD1 | c.5372C>T p.S1791F | Missense Mutation (SNP) | VAF 139/296 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAP3K7 | c.1411A>G p.T471A (on ENST00000369329 / NM_145331.3; = p.T444A on NM_003188.4) | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MBD1 | c.994C>T p.R332C (on ENST00000269468 / NM_001323950.1; = p.R309C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MCM3AP | c.2949C>G p.F983L | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIPOL1 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 63/424 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MNDA | c.1098A>T p.K366N | Missense Mutation (SNP) | VAF 236/629 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MRGPRG | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 126/627 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- MUC16 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 189/553 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- MUC4 | c.14617C>A p.Q4873K (on ENST00000463781 / NM_018406.7; = p.Q637K on NM_004532.6) | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH6 | c.5163G>A p.Q1721= | Splice Region (SNP) | VAF 60/361 reads (17%) | called by muse, mutect2, varscan2
- MYO15B | c.3847A>G p.I1283V | Missense Mutation (SNP) | VAF 141/341 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MYOT | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 103/363 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAIP | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 191/782 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCKAP5 | c.5671G>A p.G1891R | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NCOA4 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCOR2 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 95/567 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDST4 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- NEB | c.6562G>A p.E2188K | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- NFKBIE | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 90/657 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOA1 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 95/367 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- NRCAM | c.1558A>G p.T520A (on ENST00000379028 / NM_001371124.1; = p.T514A on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/546 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRK | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR2L13 | c.32T>G p.F11C | Missense Mutation (SNP) | VAF 130/443 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR52E1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- OR52I1 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 62/394 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR5D13 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 160/422 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OSTF1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 228/434 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAK6 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAWR | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PCDHA7 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 172/656 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PCDHA8 | c.1032T>A p.N344K | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB15 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 129/484 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCSK7 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by mutect2, varscan2
- PDE5A | c.2129A>G p.K710R | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDGFRA | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDZD3 | c.1364A>G p.D455G (on ENST00000531114; = p.D375G on NM_024791.4) | Missense Mutation (SNP) | VAF 75/484 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PGLYRP4 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 222/623 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PGR | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 78/403 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHEX | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.326); called by muse, varscan2
- PKHD1 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLEKHG3 | c.571G>A p.E191K (on ENST00000394691; = p.E247K on NM_001308147.2) | Missense Mutation (SNP) | VAF 220/411 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLXNA4 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 116/653 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLI | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- POLK | c.2245G>C p.V749L | Missense Mutation (SNP) | VAF 110/363 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLQ | c.3278A>G p.N1093S | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEE | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- POTEJ | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PRAMEF18 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 86/495 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRAMEF19 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 90/1034 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2
- PROS1 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR35 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRSS12 | c.2320G>A p.G774R | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- REELD1 | c.909-1G>A p.X303_splice | Splice Site (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- RGS17 | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNH1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 136/400 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- RP1 | c.3578A>C p.H1193P | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL10L | c.49T>A p.Y17N | Missense Mutation (SNP) | VAF 239/467 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- RPL27A | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- SARDH | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 200/350 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SCN11A | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SCN4A | c.4080G>A p.M1360I | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); called by muse, mutect2
- SDK1 | c.5408G>A p.G1803E | Missense Mutation (SNP) | VAF 185/415 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SGPP2 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.2246G>A p.G749E | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SLC26A7 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLFN14 | c.2668C>T p.H890Y | Missense Mutation (SNP) | VAF 75/373 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMARCAL1 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA3 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 135/524 reads (26%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- SPATA31A1 | c.1097T>C p.L366S | Missense Mutation (SNP) | VAF 193/574 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SPHKAP | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTLC1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRPX2 | c.1340A>T p.Y447F | Missense Mutation (SNP) | VAF 103/363 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ST8SIA3 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 111/424 reads (26%) | PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SUPT6H | c.4997C>T p.S1666F | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TAS2R9 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 292/717 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENM4 | c.7682C>T p.S2561F | Missense Mutation (SNP) | VAF 91/552 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TEX46 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMC5 | c.1705A>T p.I569F (on ENST00000396229 / NM_001105248.1; = p.I323F on NM_024780.5) | Missense Mutation (SNP) | VAF 147/426 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TMEM161A | c.1031G>C p.R344P | Missense Mutation (SNP) | VAF 208/687 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TNFRSF18 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 220/543 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNRC6B | c.4926_4928delinsTT p.S1643* (on ENST00000454349 / NM_001162501.2; = p.S1533* on NM_015088.3) | Frame Shift Del (DEL) | VAF 117/407 reads (29%) | called by pindel, varscan2*
- TRPV4 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 100/526 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- TRPV5 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL6 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- TTN | c.7025G>A p.G2342E (on ENST00000591111; = p.G2296E on NM_003319.4) | Missense Mutation (SNP) | VAF 58/282 reads (21%) | PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TTN | c.5180C>T p.T1727I (on ENST00000591111; = p.T1681I on NM_003319.4) | Missense Mutation (SNP) | VAF 108/436 reads (25%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGGT2 | c.2534A>T p.Y845F | Missense Mutation (SNP) | VAF 109/218 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UGT2A1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WASHC2A | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR76 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WFDC5 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 168/516 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.535G>A p.D179N (on ENST00000628543; = p.D354N on NM_152381.6) | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- XKRX | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XPO4 | c.2879A>G p.N960S | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ZAN | c.2967A>C p.K989N | Missense Mutation (SNP) | VAF 142/672 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.401); called by mutect2, varscan2
- ZDBF2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFP42 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF283 | c.1711T>G p.F571V | Missense Mutation (SNP) | VAF 127/537 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZNF540 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF564 | c.632T>A p.L211* | Nonsense Mutation (SNP) | VAF 197/589 reads (33%) | called by muse, mutect2, varscan2
- ZNF723 | c.716A>T p.N239I | Missense Mutation (SNP) | VAF 190/401 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); called by muse, varscan2
- ZNF723 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, varscan2
- ZNF891 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- A3GALT2 | c.480G>A p.V160= | Silent (SNP) | VAF 100/508 reads (20%) | catalogued as rs761572771; called by muse, mutect2, varscan2
- ABCC6 | c.576C>T p.F192= | Silent (SNP) | VAF 35/261 reads (13%) | called by muse, mutect2, varscan2
- ACAA2 | c.178C>T p.L60= | Silent (SNP) | VAF 37/164 reads (23%) | called by muse, mutect2, varscan2
- ACAA2 | c.177C>T p.V59= | Silent (SNP) | VAF 37/166 reads (22%) | called by muse, mutect2, varscan2
- ACSS3 | c.1860G>A p.V620= | Silent (SNP) | VAF 78/492 reads (16%) | called by muse, mutect2, varscan2
- ACSS3 | c.2047C>T p.L683= | Silent (SNP) | VAF 127/310 reads (41%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.600G>A p.A200= | Silent (SNP) | VAF 266/641 reads (41%) | catalogued as rs759827399, COSV58444848; called by muse, mutect2, varscan2
- ADGRE1 | c.1803C>T p.S601= | Silent (SNP) | VAF 96/299 reads (32%) | catalogued as rs972254226; called by muse, mutect2, varscan2
- AL136295.1 | c.1506C>T p.I502= | Silent (SNP) | VAF 308/624 reads (49%) | catalogued as rs749354709, COSV55782028; called by muse, mutect2, varscan2
- ALMS1 | c.193C>T p.L65= | Silent (SNP) | VAF 100/423 reads (24%) | called by muse, mutect2, varscan2
- ANKFN1 | c.319C>T p.L107= | Silent (SNP) | VAF 84/470 reads (18%) | called by muse, mutect2, varscan2
- ANKRD33 | c.336C>T p.F112= (on ENST00000340970 / NM_001304459.2; = p.F237= on NM_182608.4) | Silent (SNP) | VAF 116/598 reads (19%) | catalogued as rs748639822; called by muse, mutect2, varscan2
- ATP13A5 | c.643C>T p.L215= | Silent (SNP) | VAF 62/321 reads (19%) | called by muse, mutect2, varscan2
- ATP2A3 | c.2706C>T p.S902= | Silent (SNP) | VAF 88/470 reads (19%) | catalogued as rs771653439; called by muse, mutect2, varscan2
- ATXN1 | c.1218C>T p.S406= | Silent (SNP) | VAF 86/511 reads (17%) | catalogued as COSV55208722; called by muse, mutect2, varscan2
- AVIL | c.396C>T p.D132= | Silent (SNP) | VAF 54/289 reads (19%) | catalogued as rs766616261; called by muse, mutect2, varscan2
- BCLAF3 | c.240C>G p.S80= | Silent (SNP) | VAF 95/282 reads (34%) | called by muse, mutect2, varscan2
- BPTF | c.8622G>A p.T2874= | Silent (SNP) | VAF 42/256 reads (16%) | catalogued as rs1251996070; called by muse, mutect2, varscan2
- C12orf4 | c.219C>T p.S73= | Silent (SNP) | VAF 196/455 reads (43%) | catalogued as COSV54209327, COSV99712801; called by muse, mutect2, varscan2
- C16orf96 | c.3015C>T p.I1005= | Silent (SNP) | VAF 133/304 reads (44%) | catalogued as rs1308236578; called by muse, mutect2, varscan2
- C2CD2L | c.1677C>T p.S559= | Silent (SNP) | VAF 97/452 reads (21%) | called by muse, mutect2, varscan2
- C2CD4D | c.316C>T p.L106= | Silent (SNP) | VAF 322/806 reads (40%) | called by muse, mutect2, varscan2
- C8G | c.147G>A p.G49= | Silent (SNP) | VAF 125/350 reads (36%) | called by muse, mutect2, varscan2
- CACNA1S | c.2466C>T p.I822= | Silent (SNP) | VAF 142/384 reads (37%) | called by muse, mutect2
- CAGE1 | c.1725C>T p.V575= (on ENST00000512086; = p.V439= on NM_205864.3) | Silent (SNP) | VAF 157/342 reads (46%) | catalogued as COSV57078973; called by muse, mutect2, varscan2
- CAPN9 | c.870C>T p.S290= | Silent (SNP) | VAF 89/649 reads (14%) | catalogued as rs776740536; called by muse, mutect2, varscan2
- CASR | c.1944C>T p.F648= (on ENST00000490131; = p.F725= on NM_000388.4) | Silent (SNP) | VAF 94/512 reads (18%) | catalogued as rs1474434486, COSV56134256; called by muse, mutect2, varscan2
- CATSPERG | c.2565T>C p.G855= | Silent (SNP) | VAF 74/403 reads (18%) | called by muse, mutect2, varscan2
- CCDC34 | c.849G>A p.A283= | Silent (SNP) | VAF 144/403 reads (36%) | catalogued as rs749059795, COSV60820825; called by muse, mutect2, varscan2
- CD163L1 | c.2265G>A p.S755= | Silent (SNP) | VAF 145/581 reads (25%) | catalogued as rs927645840, COSV58016797; called by muse, mutect2, varscan2
- CD8B | c.438G>A p.K146= | Silent (SNP) | VAF 37/218 reads (17%) | catalogued as rs1236954644; called by muse, mutect2, varscan2
- CDC42BPB | c.4680C>T p.V1560= | Silent (SNP) | VAF 61/445 reads (14%) | catalogued as COSV100775616; called by muse, mutect2, varscan2
- CDH24 | c.1740C>T p.S580= | Silent (SNP) | VAF 206/459 reads (45%) | called by muse, mutect2, varscan2
- CDH24 | c.1494C>T p.A498= | Silent (SNP) | VAF 141/267 reads (53%) | called by muse, varscan2
- CHGA | c.108C>T p.I36= | Silent (SNP) | VAF 77/533 reads (14%) | catalogued as rs376854650; called by muse, mutect2, varscan2
- CHSY3 | c.2635C>A p.R879= | Silent (SNP) | VAF 30/247 reads (12%) | catalogued as rs201876337, COSV59272695; called by muse, mutect2, varscan2
- CIAPIN1 | c.258C>T p.I86= | Silent (SNP) | VAF 77/444 reads (17%) | called by muse, mutect2, varscan2
- CNGA2 | c.1194C>T p.F398= | Silent (SNP) | VAF 105/310 reads (34%) | catalogued as rs1351027080, COSV61703840; called by muse, mutect2, varscan2
- CNTNAP4 | c.2625G>A p.Q875= | Silent (SNP) | VAF 84/464 reads (18%) | called by muse, mutect2, varscan2
- CTR9 | c.729C>T p.L243= | Silent (SNP) | VAF 60/299 reads (20%) | called by muse, mutect2, varscan2
- CUX2 | c.3942G>A p.Q1314= | Silent (SNP) | VAF 103/612 reads (17%) | catalogued as rs373830228; called by muse, mutect2, varscan2
- DAB1 | c.1323G>A p.Q441= (on ENST00000371231; = p.Q408= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 76/481 reads (16%) | catalogued as rs866588545, COSV100976509; called by muse, mutect2, varscan2
- DBX2 | c.816C>T p.F272= | Silent (SNP) | VAF 96/535 reads (18%) | catalogued as COSV60336483; called by muse, mutect2, varscan2
- DHX16 | c.1596C>T p.L532= | Silent (SNP) | VAF 379/789 reads (48%) | called by muse, mutect2, varscan2
- DNAH5 | c.963G>A p.S321= | Silent (SNP) | VAF 98/305 reads (32%) | catalogued as rs758493084, COSV54205236; called by muse, mutect2, varscan2
- DNAH9 | c.4203G>A p.Q1401= | Silent (SNP) | VAF 201/493 reads (41%) | called by muse, mutect2, varscan2
- DOCK3 | c.1413G>A p.R471= | Silent (SNP) | VAF 60/295 reads (20%) | catalogued as rs775363635; called by muse, mutect2, varscan2
- DTX3 | c.432C>T p.P144= | Silent (SNP) | VAF 59/350 reads (17%) | catalogued as rs547949460; called by muse, mutect2, varscan2
- DZIP1 | c.2151G>A p.V717= (on ENST00000347108; = p.V698= on NM_014934.5) | Silent (SNP) | VAF 257/537 reads (48%) | catalogued as rs1184683485; called by muse, mutect2, varscan2
- EHBP1L1 | c.3015C>T p.A1005= | Silent (SNP) | VAF 209/560 reads (37%) | called by muse, varscan2
- ENOSF1 | c.492G>A p.A164= (on ENST00000340116 / NM_001354066.2; = p.A116= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/517 reads (15%) | catalogued as rs779968077; called by muse, mutect2, varscan2
- ERC2 | c.1161C>T p.I387= | Silent (SNP) | VAF 95/287 reads (33%) | catalogued as rs755705170, COSV55616908, COSV55658146; called by muse, mutect2, varscan2
- ERC2 | c.1032G>A p.V344= | Silent (SNP) | VAF 61/393 reads (16%) | catalogued as rs1031350431, COSV55611741; called by muse, mutect2, varscan2
- FANCE | c.1068C>T p.S356= | Silent (SNP) | VAF 75/531 reads (14%) | catalogued as rs748538800; called by muse, mutect2, varscan2
- FCRL1 | c.663G>A p.V221= | Silent (SNP) | VAF 148/496 reads (30%) | called by muse, mutect2, varscan2
- FEZ1 | c.138T>A p.L46= | Silent (SNP) | VAF 93/467 reads (20%) | called by muse, mutect2, varscan2
- FILIP1 | c.2043A>C p.L681= | Silent (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- FLT1 | c.3948G>A p.R1316= | Silent (SNP) | VAF 78/518 reads (15%) | catalogued as COSV56716496; called by muse, mutect2, varscan2
- FMN2 | c.474G>A p.P158= | Silent (SNP) | VAF 109/667 reads (16%) | catalogued as rs1198977248, COSV60417397; called by muse, mutect2, varscan2
- FOCAD | c.3939C>T p.T1313= | Silent (SNP) | VAF 112/204 reads (55%) | catalogued as rs1220802156; called by muse, mutect2, varscan2
- FTH1 | c.93C>T p.A31= | Silent (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
- GALNT16 | c.597G>A p.A199= | Silent (SNP) | VAF 65/444 reads (15%) | catalogued as rs767116865, COSV61886595; called by muse, mutect2, varscan2
- GFPT2 | c.1131C>T p.T377= | Silent (SNP) | VAF 98/408 reads (24%) | called by muse, mutect2, varscan2
- GJB5 | c.429C>T p.I143= | Silent (SNP) | VAF 82/433 reads (19%) | catalogued as rs368619804; called by muse, mutect2, varscan2
- GTF2H2C | c.444C>T p.S148= | Silent (SNP) | VAF 122/362 reads (34%) | catalogued as COSV66287348; called by muse, mutect2, varscan2
- H4C9 | c.201C>T p.I67= | Silent (SNP) | VAF 93/687 reads (14%) | called by muse, mutect2, varscan2
- HEY2 | c.834C>T p.F278= | Silent (SNP) | VAF 102/526 reads (19%) | called by muse, mutect2, varscan2
- HLF | c.801C>T p.L267= | Silent (SNP) | VAF 158/423 reads (37%) | called by muse, mutect2, varscan2
- HYDIN | c.5301C>T p.F1767= | Silent (SNP) | VAF 44/330 reads (13%) | catalogued as rs1236938645; called by muse, mutect2
- IGHV2OR16-5 | c.24C>T p.L8= | Silent (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- IGHV3-20 | c.183G>A p.G61= | Silent (SNP) | VAF 64/388 reads (16%) | catalogued as rs550061710; called by muse, mutect2
- IGKV1-12 | c.303G>A p.Q101= | Silent (SNP) | VAF 58/483 reads (12%) | catalogued as rs1421213244; called by muse, mutect2, varscan2
- IGLON5 | c.342C>T p.F114= | Silent (SNP) | VAF 177/456 reads (39%) | called by muse, mutect2, varscan2
- IKZF5 | c.939A>G p.P313= | Silent (SNP) | VAF 91/393 reads (23%) | called by muse, mutect2, varscan2
- INPPL1 | c.2574C>T p.H858= | Silent (SNP) | VAF 79/476 reads (17%) | called by muse, mutect2, varscan2
- IRF6 | c.741G>A p.Q247= | Silent (SNP) | VAF 251/587 reads (43%) | called by muse, mutect2, varscan2
- ITGA11 | c.918G>A p.R306= | Silent (SNP) | VAF 118/388 reads (30%) | catalogued as COSV59874925; called by muse, mutect2, varscan2
- ITLN1 | c.513G>A p.T171= | Silent (SNP) | VAF 254/627 reads (41%) | catalogued as rs142129957, COSV58275918; called by muse, mutect2, varscan2
- ITPR1 | c.2919G>A p.L973= (on ENST00000354582; = p.L958= on NM_002222.7) | Silent (SNP) | VAF 109/288 reads (38%) | catalogued as rs777422804; called by muse, mutect2, varscan2
- JHY | c.2292G>A p.R764= | Silent (SNP) | VAF 172/402 reads (43%) | called by muse, mutect2, varscan2
- KCNK9 | c.981C>T p.F327= | Silent (SNP) | VAF 74/414 reads (18%) | catalogued as COSV57286233; called by muse, mutect2, varscan2
- KCNMA1 | c.951C>T p.F317= | Silent (SNP) | VAF 86/193 reads (45%) | called by muse, mutect2, varscan2
- KIAA1549 | c.1425G>A p.E475= | Silent (SNP) | VAF 52/352 reads (15%) | called by muse, mutect2, varscan2
- KIF20B | c.1030T>C p.L344= | Silent (SNP) | VAF 49/212 reads (23%) | catalogued as rs146702249; called by muse, mutect2, varscan2
- KIF4B | c.2898G>A p.Q966= | Silent (SNP) | VAF 151/469 reads (32%) | catalogued as rs1309380044; called by muse, mutect2, varscan2
- KIF7 | c.1203C>T p.A401= | Silent (SNP) | VAF 105/290 reads (36%) | called by muse, varscan2
- KLF14 | c.345C>T p.S115= | Silent (SNP) | VAF 122/766 reads (16%) | called by muse, mutect2
- LCN8 | c.111G>A p.R37= (on ENST00000612714 / NM_001345934.1; = p.R14= on NM_178469.3) | Silent (SNP) | VAF 221/393 reads (56%) | catalogued as rs1189357148; called by muse, mutect2, varscan2
- LPP | c.1201C>T p.L401= | Silent (SNP) | VAF 97/543 reads (18%) | called by muse, mutect2, varscan2
- LRRC31 | c.1491T>C p.D497= | Silent (SNP) | VAF 175/425 reads (41%) | called by muse, mutect2, varscan2
- LRRC8A | c.2100C>T p.L700= | Silent (SNP) | VAF 293/511 reads (57%) | called by muse, mutect2, varscan2
- LRTM1 | c.369G>A p.Q123= | Silent (SNP) | VAF 96/306 reads (31%) | catalogued as rs766117773, COSV99836032; called by muse, mutect2, varscan2
- MDM1 | c.2076T>C p.S692= | Silent (SNP) | VAF 106/278 reads (38%) | called by muse, mutect2, varscan2
- MGAM2 | c.1899G>A p.R633= | Silent (SNP) | VAF 186/369 reads (50%) | catalogued as rs1299999958; called by muse, mutect2, varscan2
- MLXIP | c.1023C>T p.S341= | Silent (SNP) | VAF 65/354 reads (18%) | catalogued as rs1049739654, COSV59834153; called by muse, mutect2, varscan2
- MRAP2 | c.6C>T p.S2= | Silent (SNP) | VAF 47/225 reads (21%) | catalogued as rs772804049; called by muse, mutect2, varscan2
- MRGPRD | c.819C>T p.P273= | Silent (SNP) | VAF 68/314 reads (22%) | catalogued as rs368476984; called by muse, varscan2
- MRGPRG | c.327C>T p.F109= | Silent (SNP) | VAF 127/628 reads (20%) | catalogued as COSV60040098; called by muse, mutect2, varscan2
- MUC5AC | c.1791C>T p.F597= | Silent (SNP) | VAF 109/477 reads (23%) | catalogued as COSV62253495; called by muse, mutect2, varscan2
- NBEAL2 | c.6402C>T p.A2134= | Silent (SNP) | VAF 55/393 reads (14%) | called by muse, mutect2, varscan2
- NCOR2 | c.2484G>A p.E828= | Silent (SNP) | VAF 93/566 reads (16%) | catalogued as rs1403747572; called by muse, mutect2, varscan2
- NFRKB | c.3783C>T p.I1261= (on ENST00000446488 / NM_001143835.2; = p.I1286= on NM_006165.3) | Silent (SNP) | VAF 105/280 reads (38%) | catalogued as COSV55655058; called by muse, mutect2, varscan2
- NINL | c.2676C>T p.A892= | Silent (SNP) | VAF 194/593 reads (33%) | called by muse, mutect2, varscan2
- NLGN2 | c.1584C>T p.V528= | Silent (SNP) | VAF 53/261 reads (20%) | called by muse, mutect2, varscan2
- NLRP14 | c.882G>A p.R294= | Silent (SNP) | VAF 178/436 reads (41%) | called by muse, mutect2, varscan2
- NLRP9 | c.1041G>A p.V347= | Silent (SNP) | VAF 225/493 reads (46%) | catalogued as rs146611098, COSV60459598; called by muse, mutect2, varscan2
- NMBR | c.87C>T p.F29= | Silent (SNP) | VAF 77/361 reads (21%) | catalogued as COSV99237067; called by muse, mutect2, varscan2
- NT5DC4 | c.723G>A p.S241= | Silent (SNP) | VAF 45/226 reads (20%) | catalogued as rs1057502023; called by muse, mutect2, varscan2
- NUP35 | c.63T>C p.G21= | Silent (SNP) | VAF 62/243 reads (26%) | called by muse, mutect2, varscan2
- OOSP1 | c.585C>T p.I195= | Silent (SNP) | VAF 116/324 reads (36%) | called by muse, mutect2, varscan2
- OR10A2 | c.165C>T p.F55= | Silent (SNP) | VAF 63/385 reads (16%) | catalogued as rs1264675981; called by muse, mutect2, varscan2
- OR1L3 | c.252C>T p.N84= | Silent (SNP) | VAF 291/485 reads (60%) | called by muse, mutect2, varscan2
- OR4C6 | c.114G>A p.L38= | Silent (SNP) | VAF 153/385 reads (40%) | catalogued as rs867467956, COSV58606256; called by muse, mutect2, varscan2
- OR56A5 | c.69C>T p.F23= | Silent (SNP) | VAF 77/430 reads (18%) | catalogued as COSV60826765; called by muse, mutect2, varscan2
- OR5AR1 | c.645C>T p.F215= | Silent (SNP) | VAF 137/340 reads (40%) | catalogued as rs867148047, COSV57252688; called by muse, mutect2, varscan2
- OR6C4 | c.180C>T p.F60= | Silent (SNP) | VAF 156/391 reads (40%) | catalogued as COSV67793238; called by muse, mutect2, varscan2
- OR6C4 | c.744C>T p.L248= | Silent (SNP) | VAF 73/460 reads (16%) | catalogued as COSV67793298; called by muse, mutect2, varscan2
- OR6N2 | c.264G>A p.E88= | Silent (SNP) | VAF 195/464 reads (42%) | called by muse, mutect2, varscan2
- OR8J1 | c.702G>A p.R234= | Silent (SNP) | VAF 156/410 reads (38%) | catalogued as COSV57316798; called by muse, mutect2, varscan2
- OXGR1 | c.855C>T p.I285= | Silent (SNP) | VAF 63/522 reads (12%) | catalogued as rs1240445214, COSV53657345; called by muse, mutect2, varscan2
- PARD6G | c.1078C>T p.L360= | Silent (SNP) | VAF 142/472 reads (30%) | catalogued as rs927673676, COSV62061010; called by muse, mutect2, varscan2
- PCDHA3 | c.198G>T p.V66= | Silent (SNP) | VAF 204/743 reads (27%) | called by muse, mutect2, varscan2
- PCDHA9 | c.327C>T p.I109= | Silent (SNP) | VAF 189/694 reads (27%) | catalogued as rs782403566, COSV65325951; called by muse, mutect2, varscan2
- PCDHGA12 | c.840C>T p.S280= | Silent (SNP) | VAF 115/397 reads (29%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.93C>T p.I31= | Silent (SNP) | VAF 145/494 reads (29%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1521C>T p.S507= | Silent (SNP) | VAF 198/699 reads (28%) | catalogued as COSV53908536; called by muse, mutect2, varscan2
- PCDHGB5 | c.1572C>T p.F524= | Silent (SNP) | VAF 76/595 reads (13%) | catalogued as COSV53911929; called by muse, mutect2, varscan2
- PDE6A | c.2181C>T p.P727= | Silent (SNP) | VAF 130/419 reads (31%) | catalogued as COSV54929942; called by muse, mutect2, varscan2
- PDE7B | c.1155C>T p.L385= | Silent (SNP) | VAF 82/304 reads (27%) | catalogued as COSV57510962; called by muse, mutect2, varscan2
- PER1 | c.390C>T p.A130= | Silent (SNP) | VAF 68/405 reads (17%) | catalogued as rs1242962098; called by muse, mutect2, varscan2
- PI4KA | c.4899C>A p.L1633= | Silent (SNP) | VAF 190/413 reads (46%) | catalogued as COSV99744435; called by muse, mutect2, varscan2
- PKN1 | c.1230T>C p.C410= | Silent (SNP) | VAF 175/581 reads (30%) | called by muse, mutect2, varscan2
- PLEC | c.11598C>T p.A3866= (on ENST00000322810 / NM_201380.4; = p.A3756= on NM_000445.5) | Silent (SNP) | VAF 142/738 reads (19%) | catalogued as rs1554675849; called by muse, mutect2, varscan2
- PLEKHG2 | c.2406C>T p.S802= | Silent (SNP) | VAF 103/560 reads (18%) | catalogued as rs775141676, COSV52681944; called by muse, mutect2, varscan2
- PLEKHG4B | c.729C>T p.F243= (on ENST00000283426; = p.F599= on NM_052909.5) | Silent (SNP) | VAF 110/306 reads (36%) | catalogued as rs1191372938, COSV52050088; called by muse, mutect2, varscan2
- PLEKHH1 | c.3660G>A p.R1220= | Silent (SNP) | VAF 86/455 reads (19%) | catalogued as COSV100233523; called by muse, mutect2, varscan2
- POTEF | c.2292C>T p.I764= | Silent (SNP) | VAF 118/521 reads (23%) | called by muse, mutect2, varscan2
- POTEF | c.2049G>A p.V683= | Silent (SNP) | VAF 109/418 reads (26%) | catalogued as COSV62540604; called by muse, mutect2, varscan2
- PRAMEF10 | c.1284G>A p.E428= | Silent (SNP) | VAF 46/296 reads (16%) | called by muse, mutect2, varscan2
- PRRC2B | c.5811C>T p.P1937= | Silent (SNP) | VAF 247/398 reads (62%) | catalogued as rs1239103205; called by muse, varscan2
- PTN | c.483G>A p.K161= | Silent (SNP) | VAF 182/369 reads (49%) | catalogued as rs553841477, COSV61966488; called by muse, mutect2, varscan2
- RBMXL2 | c.264G>A p.A88= | Silent (SNP) | VAF 84/442 reads (19%) | catalogued as rs1453975289, COSV60979877; called by muse, mutect2, varscan2
- RFC1 | c.2850G>A p.R950= (on ENST00000381897 / NM_001363496.2; = p.R949= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/319 reads (20%) | called by muse, mutect2, varscan2
- RGSL1 | c.468C>T p.S156= | Silent (SNP) | VAF 141/314 reads (45%) | catalogued as COSV54263722; called by muse, mutect2, varscan2
- RHO | c.162C>T p.I54= | Silent (SNP) | VAF 194/441 reads (44%) | called by muse, mutect2, varscan2
- ROS1 | c.3780G>A p.V1260= | Silent (SNP) | VAF 54/303 reads (18%) | called by muse, mutect2, varscan2
- SALL3 | c.1512C>T p.P504= | Silent (SNP) | VAF 153/609 reads (25%) | called by muse, mutect2, varscan2
- SBF2 | c.3009C>T p.F1003= | Silent (SNP) | VAF 106/512 reads (21%) | called by muse, mutect2, varscan2
- SH2B2 | c.483G>A p.S161= | Silent (SNP) | VAF 103/526 reads (20%) | catalogued as COSV60825700; called by muse, mutect2, varscan2
- SHROOM3 | c.2676C>T p.F892= | Silent (SNP) | VAF 114/498 reads (23%) | called by muse, mutect2, varscan2
- SLC17A1 | c.586C>T p.L196= | Silent (SNP) | VAF 236/507 reads (47%) | called by muse, mutect2, varscan2
- SLC1A6 | c.669C>T p.S223= | Silent (SNP) | VAF 199/648 reads (31%) | catalogued as COSV55674386; called by muse, mutect2, varscan2
- SLC26A4 | c.2163G>A p.T721= | Silent (SNP) | VAF 73/497 reads (15%) | catalogued as rs375151702, COSV55919095; called by muse, mutect2, varscan2
- SLC27A3 | c.2082C>T p.A694= (on ENST00000271857; = p.A566= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 203/746 reads (27%) | catalogued as rs766635920; called by muse, mutect2, varscan2
- SLC27A3 | c.2083C>T p.L695= (on ENST00000271857; = p.L567= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 202/745 reads (27%) | catalogued as rs1367551742; called by muse, mutect2, varscan2
- SLC4A5 | c.708C>T p.S236= | Silent (SNP) | VAF 66/274 reads (24%) | called by muse, mutect2, varscan2
- SLC52A2 | c.636G>A p.Q212= | Silent (SNP) | VAF 170/470 reads (36%) | called by muse, mutect2, varscan2
- SLC5A7 | c.438C>T p.F146= | Silent (SNP) | VAF 54/248 reads (22%) | catalogued as COSV104382779, COSV50891013; called by muse, mutect2, varscan2
- SLC6A19 | c.1503G>A p.E501= | Silent (SNP) | VAF 131/461 reads (28%) | called by muse, mutect2, varscan2
- SOX13 | c.1029C>T p.F343= | Silent (SNP) | VAF 111/445 reads (25%) | called by muse, mutect2, varscan2
- SOX4 | c.1356C>T p.P452= | Silent (SNP) | VAF 66/438 reads (15%) | catalogued as rs1268358699; called by muse, mutect2, varscan2
- SPATA13 | c.885C>T p.F295= | Silent (SNP) | VAF 63/242 reads (26%) | catalogued as rs767598950; called by muse, varscan2
- SPHKAP | c.2037C>T p.S679= | Silent (SNP) | VAF 97/360 reads (27%) | catalogued as rs866878386, COSV60895569; called by muse, mutect2, varscan2
- SPTBN2 | c.5943C>T p.A1981= | Silent (SNP) | VAF 147/380 reads (39%) | catalogued as rs761380862, COSV59448334; called by muse, mutect2, varscan2
- SPTBN5 | c.4314C>T p.L1438= | Silent (SNP) | VAF 144/459 reads (31%) | catalogued as rs762819167, COSV58028988; called by muse, mutect2, varscan2
- SSU72P2 | c.81G>A p.R27= | Silent (SNP) | VAF 162/296 reads (55%) | called by muse, varscan2
- STAC | c.801C>T p.F267= | Silent (SNP) | VAF 51/327 reads (16%) | catalogued as COSV56219559; called by muse, mutect2, varscan2
- SYT13 | c.453G>A p.E151= | Silent (SNP) | VAF 73/410 reads (18%) | catalogued as COSV50073335; called by muse, mutect2, varscan2
- TAAR5 | c.507C>T p.F169= | Silent (SNP) | VAF 92/333 reads (28%) | called by muse, mutect2, varscan2
- TENM1 | c.1686C>T p.S562= | Silent (SNP) | VAF 59/212 reads (28%) | catalogued as COSV64431133; called by muse, mutect2, varscan2
- TENT5D | c.678G>A p.R226= | Silent (SNP) | VAF 104/299 reads (35%) | catalogued as COSV100382791; called by muse, mutect2, varscan2
- TEX35 | c.519C>T p.P173= | Silent (SNP) | VAF 189/734 reads (26%) | catalogued as rs1000281580, COSV99274903; called by muse, mutect2, varscan2
- THSD7B | c.45G>A p.R15= | Silent (SNP) | VAF 67/323 reads (21%) | called by muse, mutect2, varscan2
- TJP3 | c.1614C>T p.I538= | Silent (SNP) | VAF 104/361 reads (29%) | called by muse, mutect2, varscan2
- TLR4 | c.387G>A p.Q129= (on ENST00000355622 / NM_138554.5; = p.Q89= on NM_003266.4) | Silent (SNP) | VAF 220/382 reads (58%) | called by muse, mutect2, varscan2
- TMEM132B | c.90G>A p.K30= | Silent (SNP) | VAF 120/338 reads (36%) | catalogued as rs1395048634; called by muse, mutect2, varscan2
- TMEM59L | c.543G>A p.G181= | Silent (SNP) | VAF 120/410 reads (29%) | called by muse, mutect2
- TNN | c.892C>T p.L298= | Silent (SNP) | VAF 141/556 reads (25%) | catalogued as COSV53429863; called by muse, varscan2
- TNNI3K | c.2301C>T p.F767= | Silent (SNP) | VAF 135/276 reads (49%) | catalogued as rs761994983, COSV53947073; called by muse, mutect2, varscan2
- TPTE | c.1437G>A p.Q479= (on ENST00000618007 / NM_199261.4; = p.Q461= on NM_199259.4) | Silent (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- TRAV24 | c.129C>T p.F43= | Silent (SNP) | VAF 68/366 reads (19%) | called by muse, mutect2, varscan2
- TRIO | c.6924C>T p.S2308= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs1194072475; called by muse, mutect2, varscan2
- TRPC3 | c.1134A>T p.S378= (on ENST00000379645 / NM_001366479.2; = p.S305= on NM_003305.2) | Silent (SNP) | VAF 73/315 reads (23%) | called by muse, mutect2, varscan2
- TSR3 | c.193T>C p.L65= | Silent (SNP) | VAF 224/555 reads (40%) | called by muse, mutect2, varscan2
- TTLL5 | c.2817C>T p.V939= | Silent (SNP) | VAF 96/594 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.13719C>T p.F4573= (on ENST00000591111; = p.F3646= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/296 reads (26%) | catalogued as rs1260191732, COSV60003173, COSV60062433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UCKL1 | c.690C>T p.S230= | Silent (SNP) | VAF 60/385 reads (16%) | catalogued as rs200733827, COSV104415217; called by muse, mutect2, varscan2
- UFC1 | c.503G>A p.*168= | Silent (SNP) | VAF 166/399 reads (42%) | called by muse, mutect2, varscan2
- UGT2A1 | c.639C>T p.F213= | Silent (SNP) | VAF 66/302 reads (22%) | catalogued as rs750373803, COSV99684795; called by muse, mutect2
- UTRN | c.8553C>T p.S2851= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as rs766359319, COSV100838745; called by muse, mutect2, varscan2
- VEGFA | c.186C>T p.F62= (on ENST00000523873 / NM_001171623.1; = p.F242= on NM_003376.6) | Silent (SNP) | VAF 73/512 reads (14%) | called by muse, mutect2, varscan2
- VN1R4 | c.171C>T p.L57= | Silent (SNP) | VAF 126/309 reads (41%) | called by muse, mutect2, varscan2
- ZC3H18 | c.333C>T p.D111= | Silent (SNP) | VAF 151/421 reads (36%) | called by muse, varscan2
- ZDBF2 | c.4020G>A p.V1340= | Silent (SNP) | VAF 82/329 reads (25%) | called by muse, mutect2, varscan2
- ZMYND8 | c.2688C>T p.V896= (on ENST00000311275 / NM_001363741.2; = p.V870= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/533 reads (32%) | called by muse, mutect2, varscan2
- ZNF275 | c.822C>T p.F274= | Silent (SNP) | VAF 84/232 reads (36%) | catalogued as COSV64704012; called by muse, mutect2, varscan2
- ZNF667 | c.258G>T p.S86= | Silent (SNP) | VAF 47/249 reads (19%) | called by muse, mutect2, varscan2
- ZNF728 | c.294G>A p.V98= | Silent (SNP) | VAF 96/258 reads (37%) | catalogued as COSV74099440; called by muse, mutect2, varscan2
- ZNF804A | c.1197G>A p.L399= | Silent (SNP) | VAF 74/329 reads (22%) | catalogued as COSV56450081; called by muse, mutect2, varscan2
- ZP2 | c.1512C>T p.S504= | Silent (SNP) | VAF 84/224 reads (38%) | called by muse, mutect2, varscan2
- ACP1 | c.231+91C>T | Intron (SNP) | VAF 97/390 reads (25%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:61497293 C>T | 5'Flank (SNP) | VAF 44/264 reads (17%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.835-252dup | Intron (INS) | VAF 71/521 reads (14%) | catalogued as rs774962385; called by mutect2, varscan2
- CAMKK1 | c.685+184C>T | Intron (SNP) | VAF 118/296 reads (40%) | called by muse, mutect2, varscan2
- CFAP99 | chr4:2459115 G>A | 5'Flank (SNP) | VAF 68/291 reads (23%) | catalogued as rs1035270628; called by muse, mutect2, varscan2
- FAM167A | c.*2617C>T | 3'UTR (SNP) | VAF 66/221 reads (30%) | catalogued as rs966308165, COSV99453114; called by muse, mutect2, varscan2
- HOXB3 | c.-159+851C>T | Intron (SNP) | VAF 58/308 reads (19%) | called by muse, mutect2, varscan2
- IRX4 | c.408-279G>A | Intron (SNP) | VAF 80/343 reads (23%) | called by muse, mutect2, varscan2
- IRX4 | c.408-280G>A | Intron (SNP) | VAF 81/347 reads (23%) | called by muse, mutect2, varscan2
- KCNMA1 | c.378+415C>T | Intron (SNP) | VAF 222/506 reads (44%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-33940G>A | Intron (SNP) | VAF 66/369 reads (18%) | catalogued as rs1217185951; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+9176C>T | Intron (SNP) | VAF 153/397 reads (39%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+19987G>A | Intron (SNP) | VAF 112/314 reads (36%) | called by muse, mutect2, varscan2
- MGAM | c.4618+289G>A | Intron (SNP) | VAF 274/368 reads (74%) | catalogued as COSV72074058; called by muse, mutect2, varscan2
- MGAM | c.4619-13700C>T | Intron (SNP) | VAF 198/250 reads (79%) | catalogued as rs765174775; called by muse, mutect2, varscan2
- MSL3 | c.102+391C>T | Intron (SNP) | VAF 82/287 reads (29%) | called by muse, mutect2, varscan2
- PFKFB3 | c.1515+1841G>A | Intron (SNP) | VAF 164/393 reads (42%) | called by muse, mutect2, varscan2
- RPA2 | chr1:27914658 C>T | 5'Flank (SNP) | VAF 142/361 reads (39%) | called by muse, mutect2, varscan2
- SIRPB1 | c.77-20211C>T | Intron (SNP) | VAF 156/232 reads (67%) | called by muse, mutect2, varscan2
- SYT7 | c.215+8850C>T | Intron (SNP) | VAF 57/355 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+1594G>A | Intron (SNP) | VAF 81/309 reads (26%) | called by muse, mutect2, varscan2
